Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACIT, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACIT-TTP1-A (Primary Tumor).

SPECIMEN(S) RECEIVED:

- A) Right lung, upper lobe, resection
- B) Lymph nodes from right lung hilus, resection
- C) Lymph nodes from lower hilus, right lung, resection
- D) Lymph nodes from middle hilus of lung, resection
- E) Right paratracheal lymph nodes, resection

CDDP-YP-ACIT-01-PR Redacted

GROSS EXAMINATION:

A) Lobe of lung measuring 12x11x4 cm, with serosa focally dull in the area of a whitish neoplasm with irregular margins, measuring 5x3.5x3 cm, located 1.7 cm from the bronchial margin of resection. The neoplasm is 0.7 cm from the visceral pleura (marked with India ink). Remainder of lung parenchyma has congested appearance. Nine lymph nodes isolated from the hilus.

A1-A3 neoplasia

A4 distant parenchyma

A5 bronchial and vascular margins of resection

A6-A7 hilar lymph nodes

B) Irregular fragment of adipose tissue measuring 3 cm in greatest diameter, from which 2 anthracotic lymph nodes isolated.

C) Five irregular blackish fragments, measuring between 0.4 cm and 1 cm in greatest diameter.

D) One blackish fragment measuring 0.6 cm in greatest diameter.

E) Irregular fragment of adipose tissue measuring 4 cm in greatest diameter, from which 3 lymph nodes isolated.

DIAGNOSIS:

A) Poorly differentiated adenocarcinoma of the lung (G3).

Emphysema of the surrounding lung parenchyma. Bronchial and vascular margins of resection free of tumor. Visceral pleura free of tumor. Chronic reactive lymph node inflammation with anthracosis in 9 hilar lymph nodes.

B-E) Reactive lymph node inflammation with anthracosis

Histopathologic staging:

1 pT2, N0

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: (R) lung, NOS C34.9

ICD-10

C34.91

fw
12/16/16

ICD-O Discrepancy		✓

Source: NCI Genomic Data Commons file 8ddfac62-2fef-483c-a4eb-2f40336ff62a (CDDP-ACIT-TTP1.CFF54005-1FAF-4D90-AEF7-D78F4CC15DEE.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).